Somatic mutation profile of tumor specimen TCGA-J8-A3O0-01A (aliquot TCGA-J8-A3O0-01A-11D-A21A-08) from TCGA case TCGA-J8-A3O0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.9 years (14,214 days).
Specimen TCGA-J8-A3O0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d958838-cf1e-4544-a6d0-a49a34c8821c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3O0-10A (Blood Derived Normal), aliquot TCGA-J8-A3O0-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33cb4803-89f9-4cea-a8fe-29fa770ff124

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 72/155 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNAJC11 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50010766; called by muse, mutect2, varscan2
- FANCD2 | c.2009T>C p.V670A | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV55035268; called by muse, mutect2, varscan2
- LTBP3 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs764981765, COSV57239263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAAL1 | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV55515025, COSV55515098; called by muse, mutect2, varscan2
- SERTAD3 | c.424T>G p.L142V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs761929429, COSV59324777; called by muse, mutect2, varscan2
- GOLGB1 | c.7880_7882del p.L2627_G2628delins* | Nonsense Mutation (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
